Somatic mutation profile of tumor specimen MMRF_2101_1_BM_CD138pos (aliquot MMRF_2101_1_BM_CD138pos_T1_KHS5U_L08148) from MMRF case MMRF_2101, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.4 years (19,871 days).
Specimen MMRF_2101_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 427cdb32-988a-41a0-aa2a-8b3c552e8ba4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2101_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2101_1_PB_Whole_C2_KHS5U_L08149; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c45af9e-dc5d-4f0d-bd8b-75f90e80b495

The open-access MAF lists 106 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 21, Intron 19, Silent 11, 3'Flank 3, RNA 3, 5'Flank 2, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 69/210 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs1031077032, COSV64419836; called by muse, mutect2, varscan2
- DHODH | c.610C>A p.L204M | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV54662415; called by muse, mutect2
- EI24 | c.711del p.N238Ifs*63 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | catalogued as COSV99629279; called by mutect2, pindel
- HARS2 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.344); catalogued as COSV51226900; called by muse, mutect2
- IGHV2-70 | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs373048671; called by muse, varscan2
- IGHV2-70 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs138836314; called by muse, varscan2
- IGLL5 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.077); catalogued as rs544778929, COSV73248964, COSV73249402; called by muse, mutect2, varscan2
- IGLV3-1 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs563308501; called by muse, varscan2
- IGLV4-3 | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs191969136; called by muse, mutect2, varscan2
- IKBKB | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100645808, COSV60598802, COSV60598896; called by muse, mutect2
- KLF4 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65929675; called by muse, mutect2
- LINGO2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs778347323, COSV58061692; called by muse, mutect2
- LOXHD1 | c.5623G>A p.V1875I (on ENST00000642948; = p.V1813I on NM_144612.7) | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs367623969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP25 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 34/532 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1375760919; called by muse, mutect2
- NEB | c.7493C>G p.P2498R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99415607; called by muse, mutect2
- OR8U1 | c.542A>C p.D181A | Missense Mutation (SNP) | VAF 117/773 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as COSV56415476; called by muse, mutect2, varscan2
- TBC1D7 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284024709; called by muse, mutect2, varscan2
- TMEM67 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768457119; called by muse, mutect2, varscan2
- TRAPPC10 | c.1687A>T p.I563L | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1569206035; called by muse, mutect2
- ZEB1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100313844; called by muse, mutect2, varscan2
- ACO1 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN2 | c.1766A>G p.Y589C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADCY2 | c.338T>G p.I113R | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- AFMID | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP10 | c.1757T>C p.M586T | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- ANO4 | c.211C>T p.P71S (on ENST00000392977 / NM_001286615.2; = p.P36S on NM_178826.4) | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.968); called by muse, mutect2
- C2orf42 | c.552T>G p.I184M | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- COG1 | c.2172G>C p.E724D | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAAF4 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- F9 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- HCFC2 | c.1157A>T p.Y386F | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HEATR5A | c.429A>T p.K143N | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HIVEP1 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 125/364 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- HSPB9 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 102/557 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LMNA | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- MUC17 | c.6746C>A p.T2249K | Missense Mutation (SNP) | VAF 64/634 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PPFIA1 | c.3268T>C p.F1090L | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTPRD | c.384_386delinsGG p.I128Mfs*7 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | called by pindel, varscan2*
- PVR | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SNED1 | c.3306C>A p.T1102= | Splice Region (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- TM9SF4 | c.1588T>A p.F530I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VILL | c.1191C>A p.C397* | Nonsense Mutation (SNP) | VAF 63/181 reads (35%) | called by muse, mutect2, varscan2
- WDR45 | c.292G>T p.E98* (on ENST00000376372 / NM_001029896.2; = p.E99* on NM_007075.3) | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | called by muse, varscan2
- ZNF600 | c.1028C>A p.S343Y | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ADAMTS7 | c.141C>T p.H47= | Silent (SNP) | VAF 43/220 reads (20%) | called by muse, mutect2, varscan2
- ADGRA2 | c.3813G>A p.Q1271= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- HMCN2 | c.11856G>C p.R3952= | Silent (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- HUWE1 | c.10935G>T p.L3645= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs782005025; called by muse, mutect2, varscan2
- MED12 | c.6195G>A p.Q2065= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1001762438, COSV61335089; called by muse, mutect2, varscan2
- MED29 | c.99C>T p.S33= (on ENST00000615911; = p.S12= on NM_017592.4) | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- NOTCH4 | c.5703G>T p.S1901= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as COSV100900267; called by muse, mutect2, varscan2
- PLAT | c.666C>T p.A222= | Silent (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- SORBS2 | c.1722C>T p.N574= | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as rs778955840, COSV53013874; called by muse, mutect2, varscan2
- TIGIT | c.174C>T p.N58= | Silent (SNP) | VAF 75/370 reads (20%) | catalogued as COSV67328785, COSV67329304; called by muse, mutect2, varscan2
- ZNF282 | c.570G>A p.K190= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1312789842; called by muse, mutect2, varscan2
- AC004593.2 | c.*1472T>A | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- ARRDC2 | c.342-68T>C | Intron (SNP) | VAF 13/219 reads (6%) | called by muse, mutect2
- BCL6 | chr3:187721728 T>C | 3'Flank (SNP) | VAF 20/81 reads (25%) | catalogued as rs993792113; called by muse, mutect2, varscan2
- BCL7A | chr12:122021572 del G | 5'Flank (DEL) | VAF 39/83 reads (47%) | catalogued as rs1235812199; called by mutect2, pindel, varscan2
- CACNG8 | c.*612C>T | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- CCDC88B | c.*295del | 3'UTR (DEL) | VAF 30/183 reads (16%) | called by mutect2, pindel, varscan2
- COL18A1 | c.3679-157G>C | Intron (SNP) | VAF 21/165 reads (13%) | catalogued as rs1428465596; called by muse, mutect2, varscan2
- DDX23 | c.620-94dup | Intron (INS) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- FER | c.*1790G>C | 3'UTR (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- FGF20 | c.*108T>A | 3'UTR (SNP) | VAF 80/186 reads (43%) | called by muse, mutect2, varscan2
- HAPLN3 | c.494-387G>A | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as rs1011165193; called by muse, mutect2, varscan2
- HECW1 | c.*1067del | 3'UTR (DEL) | VAF 6/58 reads (10%) | catalogued as rs1243272261; called by pindel, varscan2
- IGKV2-29 | n.124C>G | RNA (SNP) | VAF 43/112 reads (38%) | catalogued as rs1486319961; called by muse, mutect2, varscan2
- INPP4B | chr4:142025083 del A | 3'Flank (DEL) | VAF 40/128 reads (31%) | catalogued as rs201230840; called by mutect2, varscan2
- KCNIP3 | c.*1537G>A | 3'UTR (SNP) | VAF 19/104 reads (18%) | catalogued as rs573397969; called by muse, mutect2, varscan2
- LINC01100 | n.291G>A | RNA (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2
- LMO4 | chr1:87346966 A>C | 3'Flank (SNP) | VAF 92/188 reads (49%) | called by muse, mutect2, varscan2
- LRP1 | c.841+4008A>T | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- LRRC73 | c.-544G>C | 5'UTR (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- LTB | c.163-157T>G | Intron (SNP) | VAF 80/177 reads (45%) | called by muse, mutect2, varscan2
- LY6G5B | c.*724C>T | 3'UTR (SNP) | VAF 12/66 reads (18%) | catalogued as rs1163498335; called by muse, mutect2
- MAEA | c.252+22C>T | Intron (SNP) | VAF 117/171 reads (68%) | called by muse, mutect2, varscan2
- MAGEB4 | c.*119A>G | 3'UTR (SNP) | VAF 33/54 reads (61%) | called by muse, mutect2, varscan2
- MBNL1 | c.-1267T>C | 5'UTR (SNP) | VAF 46/240 reads (19%) | called by muse, varscan2
- MGAT4A | c.*3891G>A | 3'UTR (SNP) | VAF 52/89 reads (58%) | called by muse, mutect2, varscan2
- PKIA | c.*1299G>A | 3'UTR (SNP) | VAF 12/116 reads (10%) | catalogued as rs1042431527; called by muse, mutect2, varscan2
- PLEKHG2 | c.*183A>G | 3'UTR (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- PLTP | c.*50C>T | 3'UTR (SNP) | VAF 7/51 reads (14%) | catalogued as rs1431684147; called by muse, mutect2, varscan2
- PPP1R3F | c.1005-384C>A | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2, varscan2
- PTPN22 | c.2359+276T>C | Intron (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- RFX3 | c.*3335G>C | 3'UTR (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- SETD5 | c.72-466T>C | Intron (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- SHLD2P3 | n.2417T>C | RNA (SNP) | VAF 46/565 reads (8%) | catalogued as rs782050337; called by muse, mutect2
- SKI | c.*1217A>G | 3'UTR (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- SLC25A40 | c.742-454A>G | Intron (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- SLC35D1 | c.*4019T>C | 3'UTR (SNP) | VAF 10/22 reads (45%) | catalogued as rs963124259; called by mutect2, varscan2
- SLC9A6 | c.945+64G>A | Intron (SNP) | VAF 23/50 reads (46%) | called by mutect2, varscan2
- SMARCAD1 | c.*1594_*1595del | 3'UTR (DEL) | VAF 14/102 reads (14%) | catalogued as rs1200212838; called by pindel, varscan2
- SORCS3 | c.*1603G>T | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- SPTAN1 | c.6693-200T>G | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- SSUH2 | c.608+67C>A | Intron (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- TAF5L | c.972+1837G>T | Intron (SNP) | VAF 19/192 reads (10%) | called by muse, mutect2, varscan2
- TERF1 | c.319+161T>G | Intron (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- TLL2 | c.*1990G>C | 3'UTR (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- TMEM170B | c.*4441T>G | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2
- TMTC2 | c.*1791A>T | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- UBE2F | c.215-25dup | Intron (INS) | VAF 15/30 reads (50%) | catalogued as rs755239457; called by mutect2, varscan2
- UBE2V2 | c.17-199G>T | Intron (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- YPEL4 | c.-185+991A>T | Intron (SNP) | VAF 128/198 reads (65%) | called by muse, mutect2, varscan2
- ZEB2 | chr2:144517829 del C | 5'Flank (DEL) | VAF 10/15 reads (67%) | called by mutect2, varscan2
